Somatic mutation profile of tumor specimen TARGET-10-PARAZN-09A (aliquot TARGET-10-PARAZN-09A-01D) from TARGET case TARGET-10-PARAZN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (902 days).
Specimen TARGET-10-PARAZN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6852be06-4da5-46f0-965d-1909edb85c59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAZN-10A (Blood Derived Normal), aliquot TARGET-10-PARAZN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/352739f6-3d7a-4e8c-ace9-a03ab5cce1a8

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, 3'UTR 2, Intron 2, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC3 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); catalogued as COSV53067239; called by muse, mutect2, varscan2
- CARD6 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 7/135 reads (5%) | catalogued as COSV99621247, COSV99621277; called by muse, mutect2
- CHRNA3 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1384357086; called by muse, mutect2
- EML5 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV100715924; called by muse, mutect2
- FANCM | c.5486C>T p.S1829F | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57500861; called by muse, mutect2, varscan2
- GBP6 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV65011175; called by muse, mutect2
- GPX6 | c.47T>A p.V16D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV62658506; called by muse, mutect2, varscan2
- NCAM2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370033455; called by muse, mutect2, varscan2
- ONECUT2 | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs749383104; called by mutect2, varscan2
- RNF17 | c.1523A>G p.H508R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1228466095; called by muse, mutect2, varscan2
- TSC2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54594624; called by muse, mutect2
- UNC5A | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs149355192; called by mutect2, varscan2
- ZNF462 | c.6696-1G>C p.X2232_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52929232; called by muse, mutect2, varscan2
- ADGRV1 | c.3467T>A p.L1156H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AFF4 | c.2874G>C p.K958N | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AZIN2 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BANK1 | c.1794G>C p.K598N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- C7orf31 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.205); called by mutect2, varscan2
- C9orf64 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A3 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CSE1L | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- ECT2L | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXO47 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GAB2 | c.124G>A p.D42N (on ENST00000361507 / NM_080491.3; = p.D4N on NM_012296.3) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR3DL2 | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRT20 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LGSN | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.011); called by muse, mutect2
- MYH15 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- QSOX2 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- SLC16A1 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMOD1 | c.249G>A p.E83= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- MAPK3 | c.762C>G p.L254= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs774097550; called by muse, mutect2
- NFATC2 | c.594C>T p.P198= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs201971596; called by muse, mutect2, varscan2
- OR56A5 | c.507C>T p.L169= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- VPS13C | c.6943C>T p.L2315= (on ENST00000644861 / NM_020821.3; = p.L2272= on NM_017684.5) | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs1220973536; called by muse, mutect2
- VPS13C | c.6942T>C p.S2314= (on ENST00000644861 / NM_020821.3; = p.S2271= on NM_017684.5) | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- ZNF521 | c.21G>A p.A7= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1254011557; called by muse, mutect2, varscan2
- AC025538.1 | n.1035C>T | RNA (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- CD70 | c.*52C>G | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- GTDC1 | c.*97C>T | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2
- IFNGR2 | c.722-27C>G | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.10360+3562G>A | Intron (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
